Somatic mutation profile of tumor specimen RC-B6SM-TTP1-A (aliquot RC-B6SM-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SM, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 78.2 years (28,564 days).
Specimen RC-B6SM-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e31c10-853e-4cd7-9835-46077785c41d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SM-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SM-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b7a366c-0cf8-4a93-bfb1-5963c2d90f87

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC30A8 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, mutect2
- TRAC | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
